Somatic mutation profile of tumor specimen TCGA-CV-7254-01A (aliquot TCGA-CV-7254-01A-11D-2012-08) from TCGA case TCGA-CV-7254, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 55.6 years (20,306 days).
Specimen TCGA-CV-7254-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7670e5b5-f003-47ff-8579-4a972a2e798d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7254-10A (Blood Derived Normal), aliquot TCGA-CV-7254-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9db9800b-1236-4ee8-a168-ddfd628ffe8d

The open-access MAF lists 277 somatic variants for this specimen: 214 protein-altering or splice-affecting, 60 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 181, Silent 60, Frame Shift Del 8, Nonsense Mutation 8, Splice Site 7, Splice Region 4, Frame Shift Ins 3, Intron 2, In Frame Del 2, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 43/62 reads (69%) | hotspot (GDC flag); catalogued as rs1057519852, COSV58682976, COSV58690849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.15565G>A p.G5189R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555185701, CM138444, COSV56433046; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- RFX6 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445567359, COSV60586495, COSV60587831; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.773A>C p.E258A | Missense Mutation (SNP) | VAF 15/46 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1060501201, COSV52661460, COSV52665450, COSV52688395, COSV53578543; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD5 | c.158A>C p.E53A | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.062); catalogued as COSV99185474; called by muse, mutect2, varscan2
- ACTG2 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.887); catalogued as rs1242882385, COSV100609152; called by muse, mutect2, varscan2
- ACTR6 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.161); catalogued as COSV99498585; called by muse, mutect2, varscan2
- ADAM2 | c.226A>G p.S76G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99697281; called by muse, mutect2, varscan2
- ADCY3 | c.2525T>A p.M842K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV99568205; called by muse, mutect2, varscan2
- ADSL | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV53406844; called by muse, mutect2, varscan2
- AFDN | c.3226G>A p.E1076K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100652950; called by muse, mutect2, varscan2
- AGBL1 | c.2447G>T p.G816V | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101222966; called by muse, mutect2, varscan2
- ALDH1L2 | c.2218A>T p.I740F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99311007; called by muse, mutect2, varscan2
- ANKRD30A | c.4112A>T p.E1371V (on ENST00000611781; = p.E1315V on NM_052997.2) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV100653463; called by muse, mutect2
- ANKRD7 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV99501103; called by muse, mutect2, varscan2
- ANP32E | c.275A>C p.Y92S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV100029663; called by muse, mutect2
- ANXA11 | c.1486A>T p.I496F | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV99627108; called by muse, varscan2
- APOB | c.9581G>T p.C3194F | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV51950754; called by muse, mutect2, varscan2
- APOB | c.7921del p.I2641Sfs*26 | Frame Shift Del (DEL) | VAF 15/124 reads (12%) | catalogued as COSV51933605; called by mutect2, pindel, varscan2
- ARHGAP21 | c.2684+1G>A p.X895_splice | Splice Site (SNP) | VAF 7/86 reads (8%) | catalogued as COSV100256166; called by muse, mutect2
- ASAP1 | c.3312G>T p.W1104C | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100727234; called by muse, mutect2, varscan2
- ASPH | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101063827; called by muse, mutect2, varscan2
- ASPM | c.6768A>T p.R2256S | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99660318; called by muse, mutect2, varscan2
- ATF6 | c.937A>G p.M313V | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100909201; called by muse, mutect2
- ATIC | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52694470, COSV99377762; called by muse, mutect2, varscan2
- ATP1B4 | c.625C>A p.Q209K (on ENST00000218008 / NM_001142447.3; = p.Q205K on NM_012069.5) | Missense Mutation (SNP) | VAF 110/146 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99486322; called by muse, varscan2
- ATP6V1C2 | c.638+3_638+6del p.X213_splice | Splice Site (DEL) | VAF 38/274 reads (14%) | catalogued as rs1268283941; called by pindel, varscan2
- BCL2L13 | c.1374G>C p.K458N | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV100456259; called by muse, mutect2
- BCORL1 | c.3446G>T p.R1149L | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV99499340; called by muse, mutect2, varscan2
- BLM | c.1636G>C p.E546Q | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV100757206; called by muse, mutect2
- BMT2 | c.302+2T>C p.X101_splice | Splice Site (SNP) | VAF 36/92 reads (39%) | catalogued as COSV99774597; called by muse, mutect2, varscan2
- C10orf71 | c.1493G>C p.S498T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100110126; called by muse, mutect2, varscan2
- C2orf16 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV101284387; called by muse, mutect2
- C6orf118 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.083); catalogued as rs769894454, COSV100024472; called by muse, mutect2, varscan2
- CD300A | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV100177900; called by muse, mutect2, varscan2
- CR1 | c.3907G>T p.V1303F | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as rs772716917, COSV100887581; called by muse, mutect2, varscan2
- CSMD3 | c.9044C>A p.S3015Y (on ENST00000297405 / NM_001363185.1; = p.S2846Y on NM_052900.3) | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52299057, COSV99833420; called by muse, mutect2, varscan2
- CTNND2 | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.138); catalogued as COSV100476157; called by muse, varscan2
- DNAH5 | c.13025A>T p.K4342M | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99449434; called by muse, mutect2, varscan2
- DPP10 | c.1355T>A p.L452Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59722939; called by muse, mutect2
- EFCAB12 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs1237831746, COSV100394435, COSV100394598; called by muse, mutect2, varscan2
- EFTUD2 | c.2404C>A p.H802N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.292); catalogued as COSV53656012, COSV99493938; called by muse, mutect2
- EHMT2 | c.582G>A p.Q194= | Splice Region (SNP) | VAF 47/115 reads (41%) | catalogued as COSV100976989; called by muse, mutect2, varscan2
- EOMES | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55415730, COSV99842450; called by muse, mutect2, varscan2
- EPB41L3 | c.2595C>A p.H865Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV100547921, COSV100549050; called by muse, mutect2, varscan2
- EPX | c.517G>C p.A173P | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99836494; called by muse, mutect2, varscan2
- ESAM | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.133); catalogued as COSV99515504; called by mutect2, varscan2
- F5 | c.2011A>G p.R671G | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100889086; called by muse, mutect2, varscan2
- FAT3 | c.3129C>A p.F1043L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99965727; called by muse, mutect2, varscan2
- FCRL2 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV100829906, COSV63832527; called by muse, mutect2, varscan2
- FCRL4 | c.582G>T p.E194D | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV99619771; called by muse, varscan2
- FLG | c.8429G>T p.G2810V | Missense Mutation (SNP) | VAF 92/827 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV100911538; called by muse, varscan2
- FMN2 | c.3640G>T p.G1214C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100142277; called by muse, varscan2
- FN3KRP | c.483G>T p.Q161H | Missense Mutation (SNP) | VAF 100/324 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV99484981; called by muse, mutect2, varscan2
- FN3KRP | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 101/324 reads (31%) | catalogued as COSV99484985; called by muse, mutect2, varscan2
- FOXD4L5 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV101073134; called by mutect2, varscan2
- FPGT | c.1291G>T p.V431F | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100907094, COSV100907213; called by muse, mutect2, varscan2
- FRAS1 | c.1519C>A p.R507S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.071); catalogued as COSV99351563; called by muse, mutect2, varscan2
- FRY | c.6412G>T p.A2138S | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0.039); catalogued as COSV100969213; called by muse, mutect2, varscan2
- GMIP | c.50G>C p.R17T | Missense Mutation (SNP) | VAF 101/169 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99179243; called by muse, mutect2, varscan2
- GON7 | c.44A>T p.Q15L | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV99184250; called by muse, mutect2, varscan2
- GPR149 | c.1527A>T p.E509D | Missense Mutation (SNP) | VAF 107/208 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV101078415; called by muse, mutect2, varscan2
- GREB1 | c.56A>G p.H19R | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99302863; called by muse, varscan2
- GREB1 | c.100A>T p.R34W | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99302866; called by muse, varscan2
- GRIN2B | c.411G>A p.K137= | Splice Region (SNP) | VAF 132/290 reads (46%) | catalogued as COSV101663023; called by muse, mutect2, varscan2
- GTDC1 | c.205A>T p.N69Y | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99600316; called by muse, mutect2, varscan2
- H3-5 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs780540125, COSV61187089; called by muse, mutect2, varscan2
- HBD | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.225); catalogued as CM930385, COSV99496691; called by muse, mutect2, varscan2
- HEPACAM2 | c.959A>G p.N320S (on ENST00000394468 / NM_001039372.4; = p.N308S on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs373381341; called by muse, mutect2
- HERC2 | c.11302G>T p.A3768S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as rs1333731338, COSV99873432; called by muse, mutect2, varscan2
- HMGCS1 | c.802T>A p.C268S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.89); catalogued as COSV100284983; called by muse, mutect2, varscan2
- IGSF1 | c.3844G>T p.E1282* | Nonsense Mutation (SNP) | VAF 127/216 reads (59%) | catalogued as COSV100812067; called by muse, mutect2, varscan2
- IL1RL1 | c.1601A>C p.Q534P | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as COSV99294032; called by muse, mutect2, varscan2
- IRX2 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1260443534, COSV57414036; called by muse, mutect2, varscan2
- ITGA7 | c.1075C>G p.R359G (on ENST00000555728; = p.R315G on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99145550, COSV99151194; called by muse, mutect2, varscan2
- ITGA8 | c.1075C>A p.Q359K | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100959166; called by muse, mutect2, varscan2
- KCNH1 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763802122, COSV55080194; called by muse, mutect2, varscan2
- KCNH2 | c.2339A>T p.Y780F | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV51228742; called by muse, mutect2
- KERA | c.107C>G p.T36S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99899426; called by muse, mutect2, varscan2
- KIF1C | c.1300C>A p.Q434K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.98); PolyPhen benign (0.011); catalogued as COSV100297117; called by muse, mutect2, varscan2
- KIN | c.818G>C p.R273T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV101092540; called by mutect2, varscan2
- KRT73 | c.423C>G p.N141K | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV99988507; called by muse, mutect2, varscan2
- LCP1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100549862; called by muse, mutect2, varscan2
- LILRA6 | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.306); catalogued as COSV99557688, COSV99558807; called by muse, mutect2, varscan2
- LIPC | c.85C>G p.P29A | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.096); catalogued as rs1172048757, COSV100134549; called by muse, mutect2, varscan2
- LRP6 | c.1247A>G p.N416S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV99743211; called by muse, mutect2
- LRRC45 | c.1166A>T p.Q389L | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100141813; called by muse, mutect2, varscan2
- MAGEB6B | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs761939709; called by muse, mutect2, varscan2
- MAP3K10 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750540519, COSV53421779; called by mutect2, varscan2
- MAP3K19 | c.954A>T p.K318N | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100208518; called by muse, mutect2, varscan2
- MED24 | c.2042C>A p.T681K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.583); catalogued as COSV100673183; called by muse, mutect2, varscan2
- MGAM | c.4656G>T p.T1552= | Splice Region (SNP) | VAF 8/55 reads (15%) | catalogued as COSV72075157, COSV72075740; called by muse, mutect2, varscan2
- MGAT1 | c.884C>A p.P295Q | Missense Mutation (SNP) | VAF 20/35 reads (57%) | PolyPhen probably damaging (0.987); catalogued as COSV100286643; called by muse, mutect2, varscan2
- MGST3 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100903318; called by muse, mutect2, varscan2
- MGST3 | c.404A>T p.Q135L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100903340; called by muse, mutect2, varscan2
- MMP20 | c.830T>C p.L277P | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99497698; called by muse, mutect2, varscan2
- MPIG6B | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.693); catalogued as COSV101008092; called by muse, mutect2, varscan2
- MRS2 | c.1112A>G p.H371R | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV99218901; called by muse, mutect2, varscan2
- MXI1 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV99491332; called by muse, mutect2, varscan2
- MYH10 | c.5210G>A p.R1737Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); catalogued as rs765309529, COSV99345122; called by muse, mutect2, varscan2
- NEK10 | c.2995A>T p.N999Y | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.26); catalogued as COSV99835149; called by muse, mutect2, varscan2
- NLRP12 | c.1280C>A p.T427K | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as COSV100145246, COSV60743523; called by muse, mutect2, varscan2
- NPY2R | c.1030C>G p.Q344E | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100279629, COSV100279680; called by muse, mutect2, varscan2
- NTM | c.203G>T p.W68L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66185840; called by muse, mutect2, varscan2
- NTN3 | c.733G>C p.A245P | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV53546726, COSV99564955; called by muse, mutect2, varscan2
- NTRK3 | c.2113T>A p.Y705N | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100712718, COSV62314706; called by muse, mutect2, varscan2
- NUP210 | c.342C>A p.D114E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99596135; called by muse, mutect2, varscan2
- NUP93 | c.1235A>T p.D412V | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100360209; called by muse, mutect2, varscan2
- OPRPN | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as rs762126179, COSV68192651; called by muse, mutect2, varscan2
- OR2T11 | c.563A>T p.D188V | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746818351, COSV100424803; called by muse, mutect2, varscan2
- OR4C46 | c.368C>A p.A123D | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs370000629, COSV100060685; called by muse, mutect2, varscan2
- OR51Q1 | c.549C>A p.H183Q | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56178566; called by muse, mutect2, varscan2
- OR52B6 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV100798487; called by muse, mutect2, varscan2
- OR5AP2 | c.760G>T p.V254F | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100266196; called by muse, mutect2, varscan2
- OR5L2 | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.144); catalogued as COSV101004306; called by muse, mutect2, varscan2
- OSBPL8 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as COSV99674993, COSV99675205; called by muse, mutect2, varscan2
- PARD3B | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100593320, COSV62523560; called by muse, mutect2, varscan2
- PCBP4 | c.105+1G>T p.X35_splice | Splice Site (SNP) | VAF 17/151 reads (11%) | catalogued as rs753924526, COSV100437024; called by muse, varscan2
- PCDHB13 | c.524C>G p.P175R | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.928); catalogued as COSV99507223; called by muse, mutect2, varscan2
- PCDHB16 | c.1803G>C p.W601C | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99501986; called by muse, mutect2, varscan2
- PCDHB8 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 55/319 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.279); catalogued as rs569991554, COSV50758042, COSV99176912; called by muse, mutect2, varscan2
- PCLO | c.9847C>G p.Q3283E | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100432125; called by muse, mutect2
- PDE10A | c.996A>G p.I332M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100605044; called by muse, mutect2, varscan2
- PDE5A | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs182361575, COSV53349381; called by muse, mutect2, varscan2
- PGAP1 | c.2145G>C p.L715F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100698179; called by muse, mutect2
- PIK3C3 | c.1982A>C p.E661A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV100010873; called by muse, mutect2, varscan2
- PITX2 | c.792C>G p.Y264* (on ENST00000354925 / NM_001204397.1; = p.Y271* on NM_000325.6) | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100146308, COSV60741085; called by muse, mutect2
- PIWIL1 | c.134A>T p.E45V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.493); catalogued as COSV99806372; called by mutect2, varscan2
- PKN3 | c.2417A>G p.E806G | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV99403556; called by muse, mutect2, varscan2
- PLCL2 | c.1636A>T p.T546S (on ENST00000615277 / NM_001144382.2; = p.T420S on NM_015184.5) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV101196727; called by muse, mutect2, varscan2
- PLEKHH3 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as COSV99511953; called by muse, varscan2
- PLXNA1 | c.4576G>T p.D1526Y | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99302969; called by muse, mutect2, varscan2
- PRCP | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV100475924; called by mutect2, varscan2
- PRDM9 | c.999C>G p.F333L | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV57004578, COSV99690392; called by muse, mutect2, varscan2
- PRKD1 | c.1216C>A p.L406I | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100120215; called by muse, mutect2, varscan2
- PRKG2 | c.1526G>C p.C509S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100019807, COSV100020723; called by muse, mutect2, varscan2
- PROX1 | c.1393C>A p.H465N | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs754119506, COSV99799341; called by muse, mutect2
- PTDSS2 | c.1147T>C p.W383R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100339157; called by muse, mutect2, varscan2
- PTGFRN | c.1583G>T p.W528L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.78); catalogued as COSV101277339; called by muse, mutect2, varscan2
- PTGS1 | c.1703G>T p.C568F | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99793154; called by muse, mutect2, varscan2
- PTPN3 | c.968A>C p.Q323P | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.315); catalogued as COSV99355703; called by muse, mutect2, varscan2
- PYGO1 | c.584T>A p.V195D | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as COSV100114615; called by muse, mutect2, varscan2
- QRICH2 | c.4967C>T p.S1656L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757542078, COSV53150823; called by muse, mutect2, varscan2
- RBM41 | c.928-1G>C p.X310_splice | Splice Site (SNP) | VAF 38/107 reads (36%) | catalogued as COSV99179788; called by muse, mutect2, varscan2
- REG1A | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV99286791; called by muse, mutect2, varscan2
- REG1A | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52070649, COSV99286935; called by muse, mutect2, varscan2
- REG3G | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55452448; called by muse, mutect2, varscan2
- REM1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52429308; called by muse, mutect2, varscan2
- RIC8B | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822564; called by muse, mutect2, varscan2
- RNF213 | c.7377G>C p.M2459I | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as COSV100300500; called by muse, mutect2, varscan2
- RNF213 | c.14779C>T p.R4927W | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1383393654, COSV100300504; called by muse, mutect2, varscan2
- RNF215 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); catalogued as rs756340670, COSV99306506; called by muse, mutect2, varscan2
- RPAIN | c.61T>C p.W21R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99851620; called by muse, mutect2, varscan2
- RPAIN | c.62G>T p.W21L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99851621; called by muse, mutect2, varscan2
- RPH3A | c.1082C>A p.A361E (on ENST00000389385 / NM_001143854.2; = p.A357E on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.18); catalogued as COSV101231815; called by muse, mutect2, varscan2
- RPS6KA6 | c.142-1G>T p.X48_splice | Splice Site (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99424688; called by muse, mutect2, varscan2
- RTN4 | c.2609A>T p.E870V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100463128; called by muse, mutect2, varscan2
- RYR3 | c.4211G>A p.R1404Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.23); catalogued as rs760927000, COSV101212701; called by muse, mutect2, varscan2
- SAMD9 | c.1544G>T p.R515I | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV101180247, COSV66074756; called by muse, mutect2
- SAP130 | c.277C>G p.Q93E | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV99384649; called by muse, mutect2, varscan2
- SGCZ | c.857G>C p.C286S | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV101169385, COSV65998311; called by muse, mutect2, varscan2
- SIGLEC1 | c.2017C>T p.R673C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs748090765, COSV52475439; called by muse, mutect2, varscan2
- SIK2 | c.2092C>T p.Q698* | Nonsense Mutation (SNP) | VAF 29/109 reads (27%) | catalogued as COSV100232131; called by muse, mutect2, varscan2
- SIN3B | c.1891G>T p.V631F | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV99931689; called by muse, mutect2, varscan2
- SLC16A12 | c.1301A>T p.D434V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100370180; called by muse, mutect2
- SLC22A14 | c.327C>G p.H109Q | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV56196851, COSV99828227; called by muse, mutect2, varscan2
- SLC25A21 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV100491167, COSV58715057; called by muse, mutect2, varscan2
- SLC7A13 | c.503T>C p.V168A | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV99878852; called by muse, mutect2, varscan2
- SMARCA4 | c.3375G>T p.R1125S | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100758494; called by muse, mutect2, varscan2
- SPATA2L | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99232270; called by muse, mutect2
- STC1 | c.602A>C p.H201P | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV51689436, COSV99282485; called by muse, mutect2, varscan2
- STK36 | c.778+1G>T p.X260_splice | Splice Site (SNP) | VAF 17/107 reads (16%) | catalogued as COSV99831326; called by muse, mutect2, varscan2
- SWSAP1 | c.361A>T p.T121S (on ENST00000312423; = p.T142S on NM_175871.4) | Missense Mutation (SNP) | VAF 80/136 reads (59%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99710131; called by muse, mutect2, varscan2
- TBC1D28 | c.182G>C p.S61T | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.099); catalogued as COSV100560990; called by muse, mutect2, varscan2
- TDRD6 | c.4676C>A p.A1559E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100287538; called by mutect2, varscan2
- TECTB | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1004125101, COSV65594818, COSV65595613; called by muse, mutect2, varscan2
- TET1 | c.5471G>T p.S1824I | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs775869833, COSV101018169; called by muse, mutect2, varscan2
- TEX55 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763328373, COSV99817516; called by muse, mutect2, varscan2
- TGIF2LX | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99383308; called by muse, mutect2, varscan2
- TGM6 | c.2120G>T p.*707Lext*6 | Nonstop Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as COSV99171775; called by muse, mutect2, varscan2
- TJP2 | c.3196G>T p.E1066* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99601065; called by muse, mutect2, varscan2
- TMEM132B | c.1684T>C p.S562P | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV100169585; called by muse, mutect2, varscan2
- TMEM200A | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV99759199; called by muse, mutect2, varscan2
- TMTC2 | c.1226C>G p.T409R | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs754452313, COSV58263248; called by muse, mutect2, varscan2
- TRIM67 | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV100792115; called by muse, mutect2, varscan2
- TRIML1 | c.1208C>A p.P403H | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100205987; called by muse, mutect2, varscan2
- TTN | c.26484G>A p.W8828* (on ENST00000591111; = p.W7901* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as COSV60170793; called by muse, mutect2, varscan2
- TTN | c.14731C>T p.P4911S (on ENST00000591111; = p.P3984S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/193 reads (21%) | PolyPhen benign (0); catalogued as COSV100611448, COSV100612118; called by muse, mutect2, varscan2
- USH2A | c.5011G>T p.G1671C | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100234105; called by muse, mutect2, varscan2
- USP34 | c.10048A>T p.T3350S | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.899); catalogued as COSV100816013; called by muse, mutect2, varscan2
- USP35 | c.1592G>T p.R531L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338149382, COSV101489100; called by muse, mutect2, varscan2
- VAV1 | c.2484G>T p.R828= | Splice Region (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100409007; called by muse, mutect2, varscan2
- VAV3 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.089); catalogued as rs771418063, COSV58396151; called by muse, mutect2, varscan2
- VCAN | c.7731C>G p.I2577M | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99425645; called by muse, mutect2, varscan2
- VWA3B | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101346026; called by muse, mutect2, varscan2
- WDR90 | c.1282C>A p.Q428K | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99553334; called by muse, mutect2, varscan2
- WDR90 | c.4421A>G p.Q1474R | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99553337; called by muse, mutect2
- ZNF257 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs772592446, COSV101448096; called by muse, mutect2, varscan2
- ZNF502 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1488798182, COSV56072631; called by muse, mutect2, varscan2
- ZNF547 | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as COSV99987915; called by muse, mutect2, varscan2
- AGO3 | c.2195del p.P732Qfs*52 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- CELSR2 | c.8398_8410del p.E2800Tfs*21 | Frame Shift Del (DEL) | VAF 17/89 reads (19%) | called by mutect2, pindel, varscan2
- EFCAB7 | c.1364dup p.R456Efs*3 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | called by mutect2, pindel
- FLG | c.9463del p.Q3155Sfs*61 | Frame Shift Del (DEL) | VAF 21/221 reads (10%) | called by mutect2, varscan2
- FREM2 | c.5477_5491del p.V1826_P1830del | In Frame Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- FRG2 | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- IGHG4 | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- LAMA4 | c.597del p.F199Lfs*36 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- MAP1A | c.1771_1773del p.K591del | In Frame Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- RAD51C | c.358del p.T120Qfs*21 (on ENST00000337432 / NM_058216.3; = p.T120Qfs*32 on NM_002876.3) | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- RELN | c.9885dup p.G3296Wfs*15 | Frame Shift Ins (INS) | VAF 53/144 reads (37%) | called by mutect2, pindel, varscan2
- RHEX | c.15dup p.M6Hfs*37 | Frame Shift Ins (INS) | VAF 9/75 reads (12%) | called by mutect2, pindel
- TROAP | c.1077del p.M360Cfs*43 | Frame Shift Del (DEL) | VAF 33/254 reads (13%) | called by mutect2, pindel, varscan2
- ZNF648 | c.1437del p.Q480Sfs*12 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel, varscan2
- A4GNT | c.438C>A p.L146= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV99367836; called by muse, mutect2
- AFF3 | c.1917G>A p.K639= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV57843874; called by muse, mutect2, varscan2
- AK7 | c.1395A>G p.K465= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99967239, COSV99967308; called by muse, mutect2
- ANKRD44 | c.2367G>A p.E789= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV99984923; called by muse, mutect2, varscan2
- BCO1 | c.561C>T p.S187= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV50734428; called by muse, mutect2, varscan2
- BOC | c.2235C>A p.I745= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV56350723, COSV99848653; called by muse, mutect2, varscan2
- BRINP3 | c.114G>A p.Q38= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100818720; called by muse, mutect2, varscan2
- CCDC181 | c.888C>G p.L296= | Silent (SNP) | VAF 49/181 reads (27%) | catalogued as COSV100890313; called by muse, mutect2, varscan2
- CHRNB3 | c.153T>C p.N51= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as rs756417837, COSV99251135; called by muse, mutect2, varscan2
- CILP | c.1617C>G p.L539= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV99973346; called by muse, mutect2, varscan2
- CXorf66 | c.567A>G p.E189= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as COSV100983875; called by muse, mutect2, varscan2
- CYBB | c.324T>C p.I108= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV101059749; called by muse, mutect2, varscan2
- DCHS1 | c.780C>T p.Y260= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as rs144400127, COSV55035590; called by muse, mutect2, varscan2
- DCHS1 | c.216G>C p.T72= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100202006; called by muse, mutect2, varscan2
- DCX | c.780T>A p.A260= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV100576408; called by muse, mutect2, varscan2
- DISP1 | c.445C>T p.L149= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as rs1473058343, COSV99450906; called by muse, mutect2, varscan2
- DNAI1 | c.549C>A p.P183= | Silent (SNP) | VAF 236/363 reads (65%) | catalogued as COSV99646800; called by muse, mutect2, varscan2
- EPB41L5 | c.849G>A p.L283= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99758637, COSV99758829; called by muse, mutect2, varscan2
- FREM2 | c.7647A>T p.I2549= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs1292074844, COSV99748623; called by muse, mutect2, varscan2
- HAO1 | c.732C>A p.A244= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV101113201; called by muse, mutect2, varscan2
- HERC5 | c.1815A>G p.V605= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs1185515641, COSV99987678; called by muse, mutect2, varscan2
- INSM2 | c.222G>T p.G74= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV99354600; called by muse, mutect2, varscan2
- IQGAP2 | c.3987G>T p.A1329= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs774651588, COSV57183708, COSV99167193; called by muse, mutect2, varscan2
- KDR | c.1842C>A p.A614= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV99817578; called by muse, mutect2, varscan2
- KIF14 | c.4593C>T p.L1531= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV100950831; called by muse, mutect2, varscan2
- KIF26B | c.2488C>T p.L830= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100832326; called by muse, mutect2, varscan2
- LCE3A | c.222G>A p.Q74= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as COSV59551225; called by muse, mutect2, varscan2
- LGALS14 | c.45T>C p.P15= | Silent (SNP) | VAF 75/220 reads (34%) | catalogued as COSV100648435; called by muse, mutect2, varscan2
- MARS2 | c.27G>T p.L9= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs1293017804, COSV99986576; called by muse, mutect2, varscan2
- MCCC2 | c.1615C>T p.L539= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV100040137; called by muse, mutect2, varscan2
- MYH15 | c.3549C>T p.F1183= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV56309825; called by muse, mutect2, varscan2
- MYRIP | c.1416G>A p.L472= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as rs1202803066, COSV56867760; called by muse, mutect2, varscan2
- NDST3 | c.1809C>A p.P603= | Silent (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- NEURL1 | c.1572C>T p.C524= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV100583329; called by muse, mutect2, varscan2
- NEXN | c.453G>A p.E151= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99630362; called by muse, varscan2
- NUP50 | c.213A>G p.G71= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV100754324; called by muse, mutect2
- OR4D10 | c.171G>T p.T57= | Silent (SNP) | VAF 40/205 reads (20%) | catalogued as COSV101597011; called by muse, mutect2, varscan2
- OR8D1 | c.636A>G p.L212= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100766640; called by muse, mutect2, varscan2
- PRG2 | c.510A>G p.R170= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100314913; called by muse, mutect2, varscan2
- RASGRF1 | c.177C>T p.S59= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as COSV101369623; called by muse, mutect2
- SAMD9L | c.2484A>G p.R828= | Silent (SNP) | VAF 96/155 reads (62%) | catalogued as COSV100560658; called by muse, mutect2, varscan2
- SEC31B | c.675A>T p.I225= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100944862; called by muse, mutect2, varscan2
- SLC13A2 | c.1386C>T p.I462= | Silent (SNP) | VAF 55/168 reads (33%) | catalogued as COSV100120304; called by muse, mutect2, varscan2
- SLC7A8 | c.768G>A p.E256= | Silent (SNP) | VAF 23/176 reads (13%) | catalogued as COSV100328414; called by muse, mutect2, varscan2
- SRGN | c.45T>C p.L15= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV99653725; called by muse, mutect2, varscan2
- STARD13 | c.1827G>C p.T609= (on ENST00000336934 / NM_001243476.3; = p.T491= on NM_052851.3) | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99715829; called by muse, mutect2, varscan2
- TJP2 | c.1596G>C p.G532= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as COSV99600920, COSV99601064; called by muse, mutect2, varscan2
- TMEM130 | c.927G>A p.G309= | Silent (SNP) | VAF 63/109 reads (58%) | catalogued as COSV100228724; called by muse, mutect2, varscan2
- TOB1 | c.72T>C p.R24= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV52149861; called by muse, mutect2
- TOMM40 | c.1011G>A p.L337= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99376094; called by muse, mutect2, varscan2
- TRANK1 | c.2667G>T p.R889= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV100082789; called by muse, mutect2, varscan2
- TRPM6 | c.864C>A p.V288= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100666286; called by muse, varscan2
- TTLL10 | c.1363C>A p.R455= (on ENST00000379289 / NM_001130045.2; = p.R382= on NM_153254.3) | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV101016669, COSV64960610; called by muse, mutect2, varscan2
- UNC13C | c.1602C>T p.L534= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs1460795027, COSV99516764; called by muse, mutect2, varscan2
- VAX1 | c.283C>T p.L95= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs1383464598, COSV53327498, COSV99524110; called by muse, mutect2, varscan2
- VWA3B | c.3327T>C p.F1109= | Silent (SNP) | VAF 48/190 reads (25%) | catalogued as COSV101289423; called by muse, mutect2, varscan2
- ZFHX3 | c.3120C>G p.L1040= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs898787333, COSV51707843; called by muse, mutect2, varscan2
- ZNF518A | c.88A>C p.R30= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100283502; called by muse, mutect2, varscan2
- ZNF524 | c.555G>A p.L185= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99684564; called by muse, mutect2, varscan2
- ZNF84 | c.1248G>C p.S416= | Silent (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- CCNQP1 | n.555G>C | RNA (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- DNM1 | c.1335+1691A>G | Intron (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100359890; called by muse, mutect2, varscan2
- EIF4A1 | c.205+59A>G | Intron (SNP) | VAF 88/199 reads (44%) | catalogued as COSV99548931; called by muse, mutect2, varscan2
